Somatic mutation profile of tumor specimen TCGA-24-2260-01A (aliquot TCGA-24-2260-01A-01W-0722-08) from TCGA case TCGA-24-2260, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 74.2 years (27,112 days).
Specimen TCGA-24-2260-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5f7e20c-2d11-4dfe-af44-959cefca0b9d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-2260-11A (Solid Tissue Normal), aliquot TCGA-24-2260-11A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86c02109-070c-4226-92b8-60a900c6b754

The open-access MAF lists 72 somatic variants for this specimen: 52 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 18, Frame Shift Del 4, Nonsense Mutation 4, Frame Shift Ins 2, Intron 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 301/339 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARHGEF11 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 55/278 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.722); catalogued as rs1391083996, COSV100809669; called by muse, mutect2, varscan2
- ASB3 | c.160A>G p.N54D | Missense Mutation (SNP) | VAF 27/446 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.848); catalogued as COSV99711729; called by muse, mutect2
- BBS9 | c.302G>A p.R101K | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.336); catalogued as COSV54176906; called by muse, mutect2, varscan2
- CHST9 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 18/506 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1047731634; called by muse, mutect2
- CLEC7A | c.612-2A>C p.X204_splice (on ENST00000304084 / NM_197947.3; = p.X158_splice on NM_022570.5) | Splice Site (SNP) | VAF 60/303 reads (20%) | catalogued as COSV100045562; called by muse, mutect2, varscan2
- DDIT4L | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV56767745; called by muse, mutect2, varscan2
- DGLUCY | c.1729C>T p.Q577* | Nonsense Mutation (SNP) | VAF 27/81 reads (33%) | catalogued as rs1289197452, COSV99824009; called by muse, varscan2
- DNAH3 | c.3220A>T p.I1074F | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.292); catalogued as COSV54535349; called by muse, mutect2, varscan2
- EBF2 | c.1259C>T p.A420V | Missense Mutation (SNP) | VAF 71/151 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs371873709; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2830C>T p.R944C | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.899); catalogued as rs757609510, COSV57516988; called by muse, mutect2, varscan2
- FANCL | c.329T>C p.F110S | Missense Mutation (SNP) | VAF 55/271 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV52076032; called by muse, mutect2, varscan2
- GABRA5 | c.824C>A p.S275* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100164730, COSV100165458, COSV59485927; called by muse, varscan2
- GABRG2 | c.1163C>G p.S388C (on ENST00000361925 / NM_001375343.1; = p.S348C on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.914); catalogued as COSV62720033; called by muse, mutect2, varscan2
- GLB1L | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99850231; called by muse, mutect2, varscan2
- HEATR5B | c.5542C>A p.P1848T | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.009); catalogued as COSV51855612; called by mutect2, varscan2
- HELT | c.719dup p.V241Gfs*? | Frame Shift Ins (INS) | VAF 6/38 reads (16%) | catalogued as rs777651380; called by pindel, varscan2
- HTRA2 | c.65dup p.I23Hfs*12 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | catalogued as rs1426130296; called by pindel, varscan2
- IRS4 | c.2192G>A p.R731H | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs760806181, COSV64534896; called by muse, mutect2, varscan2
- LRRK2 | c.5357C>T p.S1786F | Missense Mutation (SNP) | VAF 392/1019 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1239894151, COSV54161227, COSV54173172; called by muse, mutect2, varscan2
- MAGED2 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV54498704; called by muse, mutect2, varscan2
- MAPK6 | c.1466A>C p.K489T | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.305); catalogued as COSV55930771; called by muse, mutect2, varscan2
- MN1 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.737); catalogued as rs1229729997, COSV56560045; called by muse, mutect2, varscan2
- MTMR10 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 150/221 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1260967466, COSV58728909; called by muse, mutect2, varscan2
- NACA2 | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 177/768 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as rs762907243, COSV71713069; called by muse, mutect2, varscan2
- OR52I1 | c.395A>G p.K132R | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.286); catalogued as COSV56169179; called by muse, mutect2, varscan2
- OTOP1 | c.1034C>T p.S345L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.023); catalogued as rs770478575, COSV56394892; called by muse, mutect2, varscan2
- PCARE | c.989G>T p.S330I | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV100527302; called by muse, mutect2
- PCDH15 | c.4933C>G p.H1645D (on ENST00000644397 / NM_001354429.2; = p.H1587D on NM_001142771.2) | Missense Mutation (SNP) | VAF 166/1851 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.162); catalogued as COSV64712088; called by muse, mutect2
- PEDS1 | c.289G>C p.G97R | Missense Mutation (SNP) | VAF 17/284 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100501898; called by muse, mutect2
- PIBF1 | c.1247A>G p.N416S | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); catalogued as rs1392888390, COSV58325573; called by mutect2, varscan2
- PTPRC | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1191758134, COSV61405688; called by muse, mutect2, varscan2
- PUM1 | c.2975C>T p.A992V | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV57085701; called by muse, mutect2, varscan2
- RBM19 | c.1981G>A p.V661I | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs754999027, COSV55695230; called by muse, mutect2, varscan2
- RGS3 | c.3535T>G p.F1179V (on ENST00000350696 / NM_001282923.2; = p.F898V on NM_130795.4) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100636558; called by mutect2, varscan2
- SIPA1L2 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53394455, COSV99477123; called by muse, mutect2
- SLC10A2 | c.395G>T p.C132F | Missense Mutation (SNP) | VAF 76/99 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV99807612; called by muse, mutect2, varscan2
- SLC38A4 | c.1526C>G p.S509* | Nonsense Mutation (SNP) | VAF 7/83 reads (8%) | catalogued as COSV99872439; called by muse, mutect2
- SMARCA4 | c.2059A>G p.K687E | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs751565055, COSV60802258; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SV2B | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs764917348, COSV57700864; called by muse, mutect2, varscan2
- TAFA4 | c.407C>T p.T136M | Missense Mutation (SNP) | VAF 46/557 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373858589, COSV55142419; called by muse, mutect2
- TEAD2 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs751545411, COSV55562252; called by muse, mutect2, varscan2
- TG | c.5374C>T p.R1792C | Missense Mutation (SNP) | VAF 70/680 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.505); catalogued as rs536801147, COSV99598973; called by muse, varscan2
- TRIM10 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 21/274 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs760940395, COSV64989959; called by muse, mutect2
- TTC21B | c.679G>T p.D227Y | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV54632616; called by muse, mutect2, varscan2
- ZC3H6 | c.3212C>T p.S1071L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV59666028; called by muse, mutect2, varscan2
- ARHGAP36 | c.249_252del p.D83Efs*16 | Frame Shift Del (DEL) | VAF 23/48 reads (48%) | called by mutect2, pindel, varscan2
- NINL | c.3603del p.R1202Efs*7 | Frame Shift Del (DEL) | VAF 16/104 reads (15%) | called by mutect2, pindel, varscan2
- SLC30A1 | c.1012_1018del p.E338Lfs*17 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | called by mutect2, pindel
- TRBV20-1 | c.102G>C p.K34N | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRIT1 | c.610del p.H204Ifs*16 | Frame Shift Del (DEL) | VAF 40/98 reads (41%) | called by mutect2, pindel, varscan2
- ZBTB11 | c.2653_2654insGGACCTAATGGGAAGT p.P885Rfs*3 | Nonsense Mutation (INS) | VAF 19/123 reads (15%) | called by mutect2, pindel
- ADAMTSL2 | c.912G>T p.G304= | Silent (SNP) | VAF 53/72 reads (74%) | catalogued as rs758446604, COSV63203238; called by muse, mutect2, varscan2
- CRTC1 | c.1641G>A p.S547= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs777830005, COSV58717261; called by muse, varscan2
- DGLUCY | c.1836C>T p.T612= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs377043453; called by muse, mutect2, varscan2
- DPP10 | c.1002A>T p.V334= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV59702832; called by muse, mutect2, varscan2
- EBLN2 | c.282A>G p.Q94= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs768254818, COSV55596816; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2928C>T p.I976= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV57516982; called by muse, mutect2
- FMO1 | c.696C>T p.D232= | Silent (SNP) | VAF 7/117 reads (6%) | catalogued as COSV100707688; called by muse, mutect2
- GSDMB | c.33T>C p.I11= | Silent (SNP) | VAF 104/256 reads (41%) | catalogued as COSV100401465; called by muse, varscan2
- KDM3A | c.714G>A p.L238= | Silent (SNP) | VAF 7/143 reads (5%) | catalogued as rs1471109914, COSV100459971; called by muse, mutect2
- KIAA1217 | c.78C>A p.G26= | Silent (SNP) | VAF 4/65 reads (6%) | catalogued as COSV100907696; called by muse, mutect2
- LTBP1 | c.1077C>T p.S359= (on ENST00000404816 / NM_206943.4; = p.S33= on NM_000627.4) | Silent (SNP) | VAF 27/241 reads (11%) | catalogued as COSV100616292; called by muse, mutect2, varscan2
- OR10H1 | c.735C>T p.H245= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV100612358; called by muse, mutect2, varscan2
- PCARE | c.987G>A p.E329= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as COSV100527305; called by muse, mutect2
- PCDHA4 | c.84C>T p.N28= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as COSV63540370; called by muse, mutect2, varscan2
- PKD1L1 | c.2433C>T p.D811= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs143429847; called by mutect2, varscan2
- POU3F3 | c.1068G>A p.S356= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs1290180343, COSV63722120; called by muse, mutect2, varscan2
- PSG9 | c.234C>T p.Y78= | Silent (SNP) | VAF 12/386 reads (3%) | catalogued as COSV52487053; called by muse, mutect2
- TCTN2 | c.1203T>A p.I401= | Silent (SNP) | VAF 43/103 reads (42%) | catalogued as COSV57633883; called by muse, mutect2, varscan2
- LNX1 | c.380+15666G>A | Intron (SNP) | VAF 30/130 reads (23%) | catalogued as rs200583618; called by muse, mutect2, varscan2
- RIMS2 | c.1692+169G>A | Intron (SNP) | VAF 28/502 reads (6%) | catalogued as rs753887468, COSV51682789; called by muse, mutect2
